TARGET case TARGET-30-PATJHU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/842d0480-79be-5c2a-99c8-4e2f5f669634

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 500 days (1.4 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 4.4 years (1,591 days); Year of diagnosis: 2010; Days to last follow up: 500 days (1.4 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 75.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 355 days; Days to first event: 355 days; First event: Relapse.
- Days to follow up: 500 days (1.4 years); Year of follow up: 2011.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PATJHU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PATJHU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 500
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Site of Relapse: Primary site; Other metastatic sites
